MMRF case MMRF_1439 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/463a106f-de45-4520-8122-aaed112641bb

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 49 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 49.9 years (18,235 days); ISS stage: I; Days to last known disease status: 253 days; Days to last follow up: 253 days.
   Treatment given: Therapeutic agents: Bortezomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 51 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 253.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -18 (ECOG 0): M Protein 0.14 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 76.4 mg/dL; Immunoglobulin G 8.93 g/L; Immunoglobulin A 0.55 g/L; Immunoglobulin M 0.23 g/L; Beta 2 Microglobulin 1.55 µg/mL; Lactate Dehydrogenase 2.6 µkat/L; Hemoglobin 7.07 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 195 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.65 mmol/L; Albumin 54 g/L; Total Protein 7.5 g/dL; Glucose 6 mmol/L; C-Reactive Protein 0.04 mg/dL.
- Day 79 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 0.672 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 43.7 mg/dL; Immunoglobulin G 8.03 g/L; Immunoglobulin A 0.44 g/L; Immunoglobulin M 0.33 g/L; Beta 2 Microglobulin 2.75 µg/mL; Hemoglobin 6.32 mmol/L; Leukocytes 12.6 ×10⁹/L; Absolute Neutrophil 10.1 ×10⁹/L; Platelets 172 ×10⁹/L; Creatinine 171 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 1.98 mmol/L; Albumin 44 g/L; Total Protein 6.6 g/dL; Glucose 7.92 mmol/L.

Other clinical attributes
- Day -18: Weight: 92 kg; Height: 162 cm.

Biospecimens (2 samples)
- Sample MMRF_1439_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -18 days.
- Sample MMRF_1439_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -18 days.
